Gene-level copy-number profile of specimen HCM-BROD-0225-C43-85N from HCMI case HCM-BROD-0225-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 42.8 years (15,646 days).
Specimen HCM-BROD-0225-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a2db042-3060-43d9-8a3f-1a9f66795b72.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0225-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/04c9abb0-a7bb-41a2-a1b6-d73783a6b0a9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 3,104; copy number 2: 55,726; copy number 3: 61.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes (within-gene range 0–2): TTC34, AC242022.2, AC242022.1.
- chr1:39,659,121–39,691,485, 2 genes: NT5C1A, HPCAL4.
- chr1:212,466,699–212,472,905, 1 gene: LINC02771.
- chr2:197,569–209,892, 1 gene: AC079779.1.
- chr3:128,572,000–128,576,086, 1 gene: LINC01565.
- chr3:196,739,857–196,832,647, 3 genes (within-gene range 0–2): PAK2, RNU4-89P, RNU6-42P.
- chr5:79,170,234–79,191,747, 2 genes (within-gene range 0–2): RNY3P1, AC016559.2.
- chr5:131,261,321–131,261,607, 1 gene (within-gene range 0–2): AC004777.1.
- chr5:174,724,582–174,730,896, 1 gene: MSX2.
- chr5:174,751,734–174,751,787, 1 gene (within-gene range 0–2): MIR4634.
- chr9:126,860,665–126,885,878, 1 gene: ZBTB34.
- chr11:14,262,846–14,273,691, 1 gene (within-gene range 0–2): SPON1-AS1.
- chr13:100,062,296–100,063,601, 1 gene: ASNSP3.
- chr13:114,314,482–114,337,626, 2 genes: CHAMP1, LINC01054.
- chr17:47,557,413–47,557,514, 1 gene (within-gene range 0–2): Y_RNA.
- chr18:45,034–73,545, 3 genes: AP001005.1, TUBB8B, AP001005.3.
- chr19:54,415,219–54,436,904, 1 gene (within-gene range 0–2): TTYH1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 248. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
